Somatic mutation profile of tumor specimen TCGA-DS-A0VM-01A (aliquot TCGA-DS-A0VM-01A-11D-A10S-08) from TCGA case TCGA-DS-A0VM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 51.6 years (18,839 days).
Specimen TCGA-DS-A0VM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998636db-b731-44af-95b0-06e562725115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A0VM-10A (Blood Derived Normal), aliquot TCGA-DS-A0VM-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/324f8f1e-0bcc-4876-ac45-c7a21cb01c5a

The open-access MAF lists 335 somatic variants for this specimen: 239 protein-altering or splice-affecting, 88 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 88, Nonsense Mutation 23, 3'Flank 3, Splice Site 3, Splice Region 2, Intron 2, 5'Flank 2, RNA 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen possibly damaging (0.64); catalogued as COSV62753842, COSV62756124, COSV62757586; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 69/135 reads (51%) | catalogued as COSV55660825; called by muse, mutect2, varscan2
- ADAMTS17 | c.1241C>G p.S414* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV51473723; called by muse, mutect2, varscan2
- ADAMTS3 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760249353, COSV54385571; called by muse, mutect2, varscan2
- ADAMTSL5 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57860131; called by muse, mutect2, varscan2
- ADGRG4 | c.2951A>T p.D984V | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs775603575, COSV54950057; called by muse, mutect2
- AKNAD1 | c.2159C>G p.S720C | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62195089; called by muse, mutect2, varscan2
- ALPK2 | c.3568G>A p.G1190R | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as COSV64490410; called by muse, mutect2, varscan2
- AOAH | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51735971, COSV99333693; called by muse, mutect2, varscan2
- ARHGEF18 | c.1902G>C p.M634I (on ENST00000359920 / NM_001130955.2; = p.M530I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV60467134; called by muse, mutect2, varscan2
- ARL14EP | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56342247; called by muse, mutect2, varscan2
- ARPP21 | c.2098C>A p.Q700K | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV51792529; called by muse, mutect2, varscan2
- ATP9A | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370100451, COSV58763395, COSV58770486; called by muse, mutect2, varscan2
- ATRIP | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57176048; called by muse, mutect2
- ATXN2 | c.1804C>T p.H602Y (on ENST00000550104; = p.H442Y on NM_002973.4) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV66481417; called by muse, mutect2, varscan2
- B3GALT1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1183217867, COSV59908082; called by muse, mutect2, varscan2
- BAZ1A | c.2939G>C p.R980T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV62409063; called by muse, mutect2, varscan2
- BBS12 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58561404; called by muse, mutect2, varscan2
- BOD1L1 | c.5937G>A p.M1979I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV50006721; called by muse, mutect2, varscan2
- BOD1L1 | c.4709G>A p.R1570K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV50006732; called by muse, mutect2, varscan2
- BRD4 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV54582599; called by muse, mutect2, varscan2
- BRMS1L | c.588C>G p.F196L | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV53762269; called by muse, mutect2
- BRWD3 | c.2925G>A p.W975* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV64744115; called by muse, mutect2
- BTC | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV67547275; called by muse, mutect2, varscan2
- C2orf78 | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV68516387; called by muse, mutect2, varscan2
- CACNA1D | c.4133G>A p.R1378K (on ENST00000350061 / NM_001128840.3; = p.R1398K on NM_000720.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.038); catalogued as COSV55438166; called by muse, mutect2, varscan2
- CAD | c.4144G>C p.E1382Q | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53023918; called by muse, mutect2, varscan2
- CARMIL2 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs779343156, COSV54665991, COSV54667818; called by muse, mutect2, varscan2
- CCAR1 | c.2881-1G>A p.X961_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | catalogued as COSV56267465, COSV99771420; called by muse, mutect2, varscan2
- CCPG1 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.432); catalogued as COSV51241181; called by muse, mutect2, varscan2
- CDC27 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV50365659; called by muse, mutect2, varscan2
- CDH10 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV52570748; called by muse, mutect2, varscan2
- CDK11B | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58336788, COSV58337098; called by muse, mutect2, varscan2
- CEP128 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 59/154 reads (38%) | catalogued as rs751491530, COSV55368687; called by muse, mutect2, varscan2
- CERK | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV53450139, COSV53453110; called by muse, mutect2, varscan2
- CHD3 | c.3004C>T p.R1002* | Nonsense Mutation (SNP) | VAF 50/162 reads (31%) | catalogued as COSV57872668; called by muse, mutect2, varscan2
- CKAP5 | c.4474G>C p.E1492Q | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV56364340; called by muse, mutect2, varscan2
- CLASP1 | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); catalogued as COSV55314584; called by muse, mutect2, varscan2
- CNDP2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60839045; called by muse, mutect2, varscan2
- CNGB1 | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV51897932; called by muse, mutect2, varscan2
- COL3A1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV58582321; called by muse, varscan2
- COL5A1 | c.5422G>A p.E1808K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV65665387; called by muse, mutect2, varscan2
- CORIN | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV56686632; called by muse, mutect2, varscan2
- CSNK1G1 | c.851-1G>C p.X284_splice | Splice Site (SNP) | VAF 55/147 reads (37%) | catalogued as COSV57306912; called by muse, mutect2, varscan2
- CTNNBIP1 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as rs1442815862, COSV65962019; called by muse, mutect2, varscan2
- CTSK | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as COSV55010741; called by muse, mutect2, varscan2
- CTSO | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260348056, COSV70808830; called by muse, mutect2, varscan2
- CYP11B2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | catalogued as COSV59994484; called by muse, varscan2
- DCAF1 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs782065552, COSV60040771; called by muse, varscan2
- DCC | c.3073C>G p.R1025G | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59083442, COSV59085855; called by muse, mutect2, varscan2
- DCLRE1C | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV63181943; called by muse, mutect2, varscan2
- DEDD | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV63501212; called by muse, mutect2, varscan2
- DENND4A | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV71265225; called by muse, mutect2, varscan2
- DLGAP5 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs766933512, COSV55962098; called by muse, mutect2, varscan2
- DMAP1 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60000001; called by muse, mutect2, varscan2
- DMBT1 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 205/330 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57532750, COSV57535112; called by muse, mutect2, varscan2
- DMD | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as CM098372, COSV55855078; called by muse, mutect2, varscan2
- EBAG9 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV61752735; called by muse, mutect2, varscan2
- EDC3 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV59339177; called by muse, mutect2, varscan2
- EGLN1 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV64147896; called by muse, mutect2, varscan2
- EIF2S1 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56451805; called by muse, mutect2, varscan2
- ENOPH1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV55022162; called by muse, mutect2
- ENPP3 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201810317, COSV62952960; called by muse, mutect2, varscan2
- EPHX2 | c.1347C>G p.F449L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV66843959; called by muse, mutect2, varscan2
- ERP44 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV52429879; called by muse, mutect2, varscan2
- FAN1 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1389922258, COSV62949763; called by muse, mutect2, varscan2
- FASN | c.7084G>A p.E2362K | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as COSV60750767; called by muse, mutect2, varscan2
- FBN1 | c.8536G>A p.E2846K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs1555393508, CM151286, COSV57309926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FDPS | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63113894; called by muse, mutect2, varscan2
- FDXR | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53120170; called by muse, mutect2, varscan2
- FGD4 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs989576032, COSV56780605; called by muse, mutect2, varscan2
- GABRG2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV62715623; called by muse, mutect2, varscan2
- GABRG3 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100407815, COSV61510781; called by muse, mutect2, varscan2
- GCM2 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65275100; called by muse, mutect2, varscan2
- GDI1 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50130746; called by muse, mutect2, varscan2
- GEN1 | c.159C>T p.L53= | Splice Region (SNP) | VAF 29/93 reads (31%) | catalogued as rs756747844, COSV58055375; called by muse, mutect2, varscan2
- GLI1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447419974, COSV57358231, COSV99954254; called by muse, mutect2, varscan2
- GNS | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs1345511245, COSV50693952; called by muse, mutect2, varscan2
- GPATCH2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65127323; called by muse, varscan2
- GPR173 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60233590; called by muse, mutect2, varscan2
- GSAP | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV57528200, COSV57528405; called by muse, mutect2, varscan2
- H3C2 | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.309); catalogued as COSV52517918, COSV52518717; called by muse, mutect2
- HECW2 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53650211; called by muse, mutect2, varscan2
- HELB | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56072250; called by muse, mutect2, varscan2
- HFM1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV54021462; called by muse, mutect2, varscan2
- HLA-F | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV52574646; called by muse, varscan2
- HNRNPH1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV61484924; called by muse, mutect2, varscan2
- HOXC4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV57697932; called by muse, varscan2
- HOXC5 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.245); catalogued as COSV54536290; called by muse, mutect2, varscan2
- IGHD | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101162812; called by muse, mutect2, varscan2
- IGSF22 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 106/162 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV60031075, COSV60039914; called by muse, mutect2, varscan2
- IL20RA | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57356461; called by muse, mutect2, varscan2
- IL9R | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV54898275; called by muse, mutect2, varscan2
- IMPG1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV64054437; called by muse, mutect2, varscan2
- INTS4 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59016430; called by muse, mutect2, varscan2
- IRS4 | c.3310C>T p.P1104S | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV64532721; called by muse, varscan2
- ITPRID1 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.706); catalogued as COSV60070440; called by muse, mutect2, varscan2
- IZUMO2 | c.417C>A p.R139= | Splice Region (SNP) | VAF 8/132 reads (6%) | catalogued as COSV53229231, COSV53229861; called by muse, mutect2
- KCTD13 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58159295; called by muse, mutect2, varscan2
- KDM4C | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 61/1023 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.682); catalogued as COSV67183816; called by muse, mutect2
- KIAA0100 | c.6586G>A p.E2196K | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV56380813; called by muse, mutect2, varscan2
- KIAA1109 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV52663057; called by muse, mutect2, varscan2
- KIF26B | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1232408087, COSV63637172; called by muse, mutect2, varscan2
- KIF7 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as COSV67997367; called by muse, mutect2, varscan2
- KMT2C | c.3556C>T p.Q1186* | Nonsense Mutation (SNP) | VAF 63/99 reads (64%) | catalogued as COSV100069595, COSV51308091; called by muse, mutect2, varscan2
- KRTAP5-8 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV68324432; called by muse, varscan2
- LAMA1 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67532475; called by muse, mutect2, varscan2
- LRBA | c.4721C>T p.S1574L | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs886443286, COSV63950248; called by muse, mutect2, varscan2
- LRP1 | c.6208G>A p.D2070N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs965146489, COSV54502633; called by muse, mutect2, varscan2
- LRRC31 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV52979606; called by muse, mutect2, varscan2
- LRRC40 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV63941612; called by muse, mutect2, varscan2
- LRRC7 | c.3536A>T p.D1179V (on ENST00000651989 / NM_001370785.2; = p.D1146V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV50413105; called by muse, mutect2, varscan2
- LRSAM1 | c.1863G>C p.E621D | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV55938364; called by muse, mutect2, varscan2
- LTBP4 | c.712G>C p.E238Q (on ENST00000308370 / NM_001042544.1; = p.E201Q on NM_003573.2) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as COSV52576639; called by muse, mutect2, varscan2
- MAGEB18 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100305660, COSV57463393; called by muse, mutect2, varscan2
- MAGEH1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV61678650; called by muse, mutect2, varscan2
- MAML1 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | catalogued as COSV52983154; called by muse, mutect2, varscan2
- MDN1 | c.1932G>C p.Q644H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV65517485; called by muse, mutect2, varscan2
- MED1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV56122482; called by muse, mutect2, varscan2
- MEPE | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV63071872; called by muse, mutect2, varscan2
- MRPS30 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.657); catalogued as COSV50181498; called by muse, mutect2, varscan2
- MTMR11 | c.1617C>G p.H539Q (on ENST00000439741 / NM_001145862.2; = p.H467Q on NM_181873.3) | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.143); catalogued as rs782333555, COSV54964297; called by muse, mutect2, varscan2
- MXRA5 | c.7145C>T p.S2382F | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV54224575; called by muse, mutect2, varscan2
- MYH14 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | catalogued as COSV51810720; called by muse, mutect2
- MYO5A | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV62556866; called by muse, mutect2, varscan2
- MYO5C | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.173); catalogued as COSV55902776, COSV55907846; called by muse, mutect2
- NAALADL2 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV70794425; called by muse, mutect2, varscan2
- NCAPG | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | catalogued as COSV52268716; called by muse, mutect2, varscan2
- NCKAP1 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.849); catalogued as COSV62939867; called by muse, mutect2, varscan2
- NEFH | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV60215254; called by muse, mutect2, varscan2
- NLRP11 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as COSV100789629, COSV64085766; called by muse, mutect2, varscan2
- NPTN | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV54736816; called by muse, mutect2, varscan2
- NR6A1 | c.813G>C p.L271F (on ENST00000487099 / NM_033334.4; = p.L266F on NM_001489.5) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); catalogued as COSV60630501; called by muse, mutect2, varscan2
- OR2B2 | c.879G>C p.R293S | Missense Mutation (SNP) | VAF 121/160 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57579113; called by muse, mutect2, varscan2
- OR5H6 | c.106C>T p.Q36* (on ENST00000642105; = p.Q20* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 113/466 reads (24%) | catalogued as COSV67351056; called by muse, mutect2, varscan2
- P3H2 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.84); catalogued as COSV60018586; called by muse, mutect2, varscan2
- PAK2 | c.437-1G>A p.X146_splice | Splice Site (SNP) | VAF 26/136 reads (19%) | catalogued as COSV59079271; called by muse, mutect2, varscan2
- PARP14 | c.4882G>C p.E1628Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772798978, COSV101506230, COSV71734152; called by muse, mutect2, varscan2
- PCDH17 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.102); catalogued as COSV64971895; called by muse, mutect2, varscan2
- PCF11 | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV53527878; called by muse, mutect2, varscan2
- PDPR | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV55349274; called by muse, mutect2, varscan2
- PDZD2 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV56851353; called by muse, mutect2, varscan2
- PHF12 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); catalogued as COSV52018184; called by muse, mutect2, varscan2
- PIWIL1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as rs777599866, COSV55344306; called by muse, mutect2, varscan2
- PKHD1L1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV65737606; called by muse, mutect2, varscan2
- PLBD1 | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53691933; called by muse, mutect2, varscan2
- PLCL2 | c.590G>A p.G197E (on ENST00000615277 / NM_001144382.2; = p.G71E on NM_015184.5) | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs77416948, COSV67620630; called by muse, mutect2, varscan2
- POU3F1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1165575427, COSV65948482; called by muse, mutect2
- PPCDC | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV61624952; called by muse, mutect2, varscan2
- PPP1R12B | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as COSV61113499; called by muse, mutect2, varscan2
- PRX | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs898471400, COSV52527810; called by muse, varscan2
- PSPH | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51908945; called by muse, mutect2, varscan2
- PTPN13 | c.1590G>C p.M530I | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV57403053, COSV57415762; called by muse, mutect2, varscan2
- PTPRK | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV63891558, COSV63898627; called by muse, mutect2, varscan2
- RASA1 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 44/65 reads (68%) | catalogued as CM1311699, COSV57191608, COSV57196650; called by muse, mutect2, varscan2
- RASGEF1A | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767084570, COSV65666676; called by muse, mutect2, varscan2
- RBM34 | c.1242G>C p.K414N | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64012323; called by muse, mutect2, varscan2
- RBM39 | c.1303C>G p.Q435E (on ENST00000253363 / NM_001323424.2; = p.Q429E on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV53613909; called by muse, varscan2
- REG1B | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59304390; called by muse, mutect2, varscan2
- RPL13A | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV52618264, COSV52619366; called by muse, mutect2, varscan2
- RPL6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52516486; called by muse, mutect2, varscan2
- RPL7A | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV59297192; called by muse, mutect2, varscan2
- RS1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 138/375 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs758816133, COSV66105892; called by muse, mutect2, varscan2
- RSPH6A | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55570095, COSV55571850; called by muse, mutect2, varscan2
- RSRC1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55823687; called by muse, mutect2, varscan2
- SAPCD1 | c.407G>A p.R136Q (on ENST00000425424; = p.R166Q on NM_001039651.1) | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as rs767770200, COSV100991755, COSV65172421; called by muse, mutect2, varscan2
- SCN8A | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100634212, COSV61976774; called by muse, varscan2
- SCNN1G | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV55597316, COSV55598867; called by muse, mutect2, varscan2
- SEMG1 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as rs565546419, COSV54871903; called by muse, mutect2, varscan2
- SENP6 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV59189543; called by muse, mutect2, varscan2
- SESN2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1245263209, COSV53426674; called by muse, mutect2, varscan2
- SGPL1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1157900784, COSV64591048; called by muse, mutect2, varscan2
- SHROOM2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV66604793; called by muse, mutect2, varscan2
- SI | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52266831; called by muse, mutect2, varscan2
- SLC12A4 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs751840065, COSV57924904; called by muse, mutect2, varscan2
- SLC1A5 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 114/336 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1184645586, COSV69466483; called by muse, mutect2, varscan2
- SLC24A5 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV58316258; called by muse, mutect2, varscan2
- SLC2A8 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs768388435, COSV64894168; called by muse, mutect2, varscan2
- SLC38A3 | c.548C>G p.S183W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV68844173; called by muse, mutect2
- SLC45A3 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV65654620; called by muse, mutect2, varscan2
- SLC4A4 | c.2659A>T p.T887S (on ENST00000264485 / NM_001098484.3; = p.T843S on NM_003759.4) | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV52615535; called by muse, mutect2, varscan2
- SLC52A2 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs782253510, COSV57350854; called by muse, mutect2, varscan2
- SLC9A5 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751861862, COSV55360308; called by muse, mutect2, varscan2
- SLC9B2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60017795; called by muse, mutect2, varscan2
- SLIT2 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV56561101; called by muse, mutect2, varscan2
- SMC6 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV61171578; called by muse, mutect2, varscan2
- SMCHD1 | c.3584C>T p.S1195L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55251141, COSV55252006; called by muse, mutect2, varscan2
- SNAI1 | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54863578; called by muse, mutect2, varscan2
- SOX2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1383072179, COSV57620964; called by muse, mutect2, varscan2
- SP7 | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 91/266 reads (34%) | catalogued as COSV58190430; called by muse, varscan2
- SP7 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.634); catalogued as COSV100381978, COSV58190441; called by muse, varscan2
- SPATA4 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771756861, COSV54588841, COSV99709006; called by muse, mutect2, varscan2
- SPATA7 | c.377C>G p.S126* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV50415821, COSV50415981; called by muse, varscan2
- SRBD1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs771443195, COSV55396009; called by muse, mutect2, varscan2
- SRCAP | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs758394442, COSV52667806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52667815; called by muse, mutect2, varscan2
- SRCAP | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs903401621, COSV52667822, COSV52677074; called by muse, mutect2, varscan2
- ST3GAL5 | c.502G>A p.E168K (on ENST00000377332; = p.E208K on NM_003896.4) | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV60385021; called by muse, mutect2, varscan2
- STAG2 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54351347; called by muse, mutect2, varscan2
- STK10 | c.2550G>T p.R850S | Missense Mutation (SNP) | VAF 135/233 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51570689, COSV51579588; called by muse, mutect2, varscan2
- SUPT6H | c.3767G>A p.R1256Q | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1352165188, COSV58924744; called by muse, mutect2, varscan2
- SYMPK | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV55609740; called by muse, mutect2, varscan2
- TANC2 | c.2803G>A p.V935M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV67330402, COSV67339706; called by muse, mutect2, varscan2
- TCERG1L | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as rs761955297, COSV64046891; called by muse, mutect2, varscan2
- TCF21 | c.373T>A p.S125T | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV52817804; called by muse, mutect2, varscan2
- TCHP | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs140118187; called by muse, mutect2, varscan2
- TENM1 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as rs759664387, COSV64425608, COSV64441267; called by muse, mutect2, varscan2
- TEX9 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100771475, COSV61876929; called by muse, mutect2, varscan2
- TMEM51 | c.325C>G p.H109D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101051524, COSV65690346; called by muse, mutect2, varscan2
- TNIK | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as rs1474128035, COSV52674240; called by muse, mutect2, varscan2
- TNRC6A | c.5220G>T p.Q1740H | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV59361483; called by muse, mutect2, varscan2
- TRAF5 | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV54821192; called by muse, mutect2, varscan2
- TRIM42 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53880392; called by muse, mutect2, varscan2
- TRO | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs776270129, COSV51497331; called by muse, mutect2, varscan2
- TSPAN8 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV56077468; called by muse, mutect2, varscan2
- TSPOAP1 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs754040639, COSV52104362; called by muse, mutect2, varscan2
- TSPYL5 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1435252640, COSV59071006; called by muse, mutect2, varscan2
- TSPYL6 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57812198; called by muse, mutect2, varscan2
- TTN | c.7243G>C p.E2415Q (on ENST00000591111; = p.E2369Q on NM_003319.4) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | PolyPhen probably damaging (0.997); catalogued as COSV59899533, COSV60079609; called by muse, mutect2, varscan2
- UGT3A2 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs542527700, COSV56928577, COSV56934463; called by muse, varscan2
- USP28 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50155888; called by muse, mutect2, varscan2
- USP34 | c.5601G>A p.M1867I | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.48); catalogued as COSV68398374; called by muse, mutect2, varscan2
- VPS13B | c.5411G>C p.R1804T | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.906); catalogued as COSV62133848; called by muse, mutect2, varscan2
- XIRP2 | c.7039C>T p.H2347Y (on ENST00000628543; = p.H2522Y on NM_152381.6) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV54683852, COSV54698097; called by muse, mutect2, varscan2
- ZBTB18 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV62396300; called by muse, mutect2, varscan2
- ZC3H14 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51767234; called by muse, mutect2, varscan2
- ZNF398 | c.586C>G p.Q196E (on ENST00000475153 / NM_170686.3; = p.Q25E on NM_020781.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1354011743, COSV60064567; called by muse, mutect2, varscan2
- ZNF442 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765275129, COSV54420408; called by muse, mutect2, varscan2
- ZNF521 | c.2457T>G p.H819Q | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV64122764; called by muse, mutect2, varscan2
- ZNF526 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55898461; called by muse, mutect2, varscan2
- ZNF700 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54310946; called by muse, mutect2, varscan2
- ZNF846 | c.1330C>G p.H444D | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101194379, COSV67411793; called by muse, mutect2, varscan2
- ZNF91 | c.1298C>G p.P433R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1359893165, COSV56080803; called by muse, mutect2, varscan2
- HTR1B | c.289_303del p.L97_L101del | In Frame Del (DEL) | VAF 38/160 reads (24%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- PRPF40B | c.605del p.P202Hfs*86 (on ENST00000380281; = p.P196Hfs*86 on NM_012272.3) | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | called by mutect2, pindel, varscan2
- YWHAZ | c.225dup p.Q76Tfs*12 | Frame Shift Ins (INS) | VAF 197/615 reads (32%) | called by mutect2, pindel, varscan2
- ZNF347 | c.437_438insCAA p.R146delinsSK | In Frame Ins (INS) | VAF 54/212 reads (25%) | called by mutect2, pindel, varscan2
- ACVR2A | c.222G>A p.V74= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs1003557227, COSV54019336; called by muse, mutect2, varscan2
- ADGRG7 | c.2184G>A p.Q728= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV56293899; called by muse, mutect2, varscan2
- AKAP4 | c.999C>T p.L333= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV62073741; called by muse, mutect2, varscan2
- ALDOA | c.1119G>A p.E373= (on ENST00000642816 / NM_001243177.4; = p.E319= on NM_184041.5) | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV57632037; called by muse, mutect2, varscan2
- ALOX5 | c.231G>A p.L77= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV65551091; called by muse, mutect2, varscan2
- AMHR2 | c.1011G>A p.Q337= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV57684943; called by muse, mutect2, varscan2
- ARHGAP30 | c.1284C>T p.L428= | Silent (SNP) | VAF 91/183 reads (50%) | catalogued as rs1220697173, COSV63514972; called by muse, mutect2, varscan2
- ARHGEF19 | c.264G>A p.E88= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV54615152; called by muse, mutect2, varscan2
- ASMTL | c.1579C>T p.L527= | Silent (SNP) | VAF 106/546 reads (19%) | catalogued as COSV67242952; called by muse, mutect2, varscan2
- BMP5 | c.1062G>A p.K354= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV63701135; called by muse, mutect2, varscan2
- BMPR2 | c.1311G>A p.Q437= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV65807613; called by muse, mutect2, varscan2
- BTLA | c.144C>T p.I48= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV57937374; called by muse, mutect2, varscan2
- CACYBP | c.123G>A p.K41= | Silent (SNP) | VAF 54/109 reads (50%) | catalogued as COSV62881032; called by muse, mutect2, varscan2
- CCDC7 | c.1182G>A p.L394= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV53226797; called by muse, mutect2, varscan2
- CD163 | c.2526T>C p.F842= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as COSV63129657; called by muse, mutect2, varscan2
- CELSR2 | c.1926C>T p.V642= | Silent (SNP) | VAF 82/235 reads (35%) | catalogued as COSV54767169, COSV54772134; called by muse, mutect2, varscan2
- CHRNB1 | c.990C>G p.L330= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV60139048; called by muse, mutect2, varscan2
- CLDN22 | c.393C>T p.V131= | Silent (SNP) | VAF 73/121 reads (60%) | catalogued as COSV60109103; called by muse, mutect2, varscan2
- CMYA5 | c.1335A>G p.A445= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as rs780060750, COSV71404144; called by muse, mutect2, varscan2
- COASY | c.24C>T p.L8= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs769397082; called by muse, mutect2, varscan2
- CRCP | c.219G>A p.L73= | Silent (SNP) | VAF 91/133 reads (68%) | catalogued as rs541770459, COSV58534691; called by muse, mutect2, varscan2
- CYP21A2 | c.534C>T p.F178= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1213332099, COSV64473985; called by muse, mutect2, varscan2
- DCLRE1A | c.2625C>T p.V875= | Silent (SNP) | VAF 67/242 reads (28%) | catalogued as COSV63748196; called by muse, mutect2, varscan2
- DEDD | c.777C>T p.F259= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as rs540627506, COSV63501209; called by muse, mutect2, varscan2
- DPP4 | c.237C>T p.F79= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV62105225; called by muse, mutect2, varscan2
- DST | c.1275G>A p.Q425= (on ENST00000361203 / NM_001374722.1; = p.Q99= on NM_001723.6) | Silent (SNP) | VAF 74/102 reads (73%) | catalogued as COSV54998987; called by muse, mutect2, varscan2
- DTX3 | c.870C>T p.L290= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV54084591; called by muse, mutect2, varscan2
- DYNC2H1 | c.3702C>G p.L1234= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100518707, COSV62086936; called by muse, mutect2, varscan2
- EDNRA | c.354G>A p.L118= | Silent (SNP) | VAF 63/209 reads (30%) | catalogued as rs201702493, COSV60095792; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELAC2 | c.1530G>A p.T510= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs202041978, COSV62031836; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELOVL6 | c.39C>T p.F13= | Silent (SNP) | VAF 26/231 reads (11%) | catalogued as rs1302104500, COSV100165479, COSV56427186; called by muse, mutect2, varscan2
- FOXD4L5 | c.981G>A p.L327= | Silent (SNP) | VAF 29/195 reads (15%) | called by mutect2, varscan2
- GALNT8 | c.549C>T p.L183= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- GBF1 | c.4845G>A p.E1615= (on ENST00000369983 / NM_001377137.1; = p.E1614= on NM_004193.3) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1405164360, COSV64142945; called by muse, mutect2, varscan2
- GDF6 | c.432G>T p.R144= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- GDF7 | c.1278C>G p.L426= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs535810550, COSV55347134; called by muse, mutect2, varscan2
- GPATCH1 | c.666C>T p.V222= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as rs1056219769, COSV50111392; called by muse, mutect2, varscan2
- GPR176 | c.297C>T p.I99= | Silent (SNP) | VAF 99/276 reads (36%) | catalogued as rs982131421, COSV54443557; called by muse, mutect2, varscan2
- HAUS5 | c.282C>T p.L94= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs570447175, COSV52546730; called by muse, mutect2, varscan2
- HYDIN | c.14772G>A p.T4924= | Silent (SNP) | VAF 26/684 reads (4%) | catalogued as rs756408083, COSV66637339; called by muse, mutect2
- IL1RL2 | c.1455C>G p.L485= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV51813113; called by muse, mutect2, varscan2
- INTS4 | c.2826C>T p.I942= | Silent (SNP) | VAF 86/253 reads (34%) | catalogued as rs1249938787, COSV59016424; called by muse, mutect2, varscan2
- ITGAL | c.108C>T p.F36= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV63320127; called by muse, mutect2, varscan2
- KDM5B | c.2961G>A p.L987= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as COSV52504504; called by muse, mutect2, varscan2
- KDM5B | c.2727G>A p.E909= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs1269088370, COSV52504510, COSV52510151; called by muse, mutect2, varscan2
- KLHL34 | c.307C>T p.L103= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV101069903, COSV65278739; called by muse, mutect2, varscan2
- KLRC1 | c.460C>T p.L154= | Silent (SNP) | VAF 102/340 reads (30%) | catalogued as COSV61724801; called by muse, mutect2, varscan2
- KSR2 | c.1447C>T p.L483= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV56666227; called by muse, mutect2, varscan2
- LLGL2 | c.612C>T p.I204= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV51342396; called by muse, mutect2, varscan2
- LMO1 | c.441C>T p.L147= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV59956537; called by muse, mutect2, varscan2
- LRRK2 | c.5928C>G p.L1976= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV54144635; called by muse, mutect2, varscan2
- LSAMP | c.894C>T p.V298= | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV61276611; called by muse, mutect2, varscan2
- MAGEE2 | c.1428C>T p.I476= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as COSV64897154, COSV64897312; called by muse, mutect2, varscan2
- MAML1 | c.2541C>T p.L847= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV52983163; called by muse, mutect2, varscan2
- MRE11 | c.1398G>A p.E466= | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as rs959415369, COSV60574102; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO7B | c.1332C>T p.F444= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs774031175, COSV67344702; called by muse, mutect2, varscan2
- NKAIN2 | c.330G>A p.E110= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs753041692, COSV63644275, COSV63687536; called by muse, mutect2, varscan2
- NRXN1 | c.1809G>A p.E603= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV58437913, COSV58444542; called by muse, mutect2, varscan2
- OR4C16 | c.849G>A p.V283= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV58940773; called by muse, mutect2, varscan2
- OR4C6 | c.276C>T p.L92= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as rs748058915, COSV58602553, COSV58605502; called by muse, mutect2, varscan2
- OR9Q1 | c.150C>T p.L50= | Silent (SNP) | VAF 105/339 reads (31%) | catalogued as rs773218353, COSV59037042; called by muse, mutect2, varscan2
- PDE4B | c.315G>C p.R105= | Silent (SNP) | VAF 24/482 reads (5%) | catalogued as COSV58467156; called by muse, mutect2
- PFKFB1 | c.606C>T p.V202= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100895623, COSV66627790; called by muse, mutect2, varscan2
- PRAMEF12 | c.54G>A p.L18= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV63214768; called by muse, mutect2, varscan2
- PRAMEF15 | c.882G>A p.L294= | Silent (SNP) | VAF 133/436 reads (31%) | called by muse, mutect2, varscan2
- PTCH2 | c.1758C>T p.D586= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs368278021; called by muse, mutect2, varscan2
- RNF213 | c.10903C>T p.L3635= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV60390758; called by muse, mutect2, varscan2
- RNF213 | c.13917C>T p.I4639= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs147013725; called by muse, mutect2, varscan2
- RPS27A | c.12C>T p.F4= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV55050280; called by muse, mutect2, varscan2
- SHCBP1 | c.94C>T p.L32= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV57646411; called by muse, varscan2
- SHKBP1 | c.192C>T p.F64= | Silent (SNP) | VAF 142/387 reads (37%) | catalogued as COSV52537706; called by muse, mutect2, varscan2
- SLC9A4 | c.411C>A p.P137= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV54829265; called by muse, mutect2, varscan2
- SLC9A7 | c.615C>T p.F205= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV60377921; called by muse, varscan2
- SORCS2 | c.2535C>T p.P845= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as rs370198948; called by muse, mutect2, varscan2
- SORL1 | c.5916C>G p.L1972= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1231344705, COSV52749697; called by muse, mutect2, varscan2
- TMEM104 | c.1089C>T p.F363= | Silent (SNP) | VAF 94/315 reads (30%) | catalogued as rs1380157850, COSV59108005; called by muse, mutect2, varscan2
- TTN | c.78486C>T p.V26162= (on ENST00000591111; = p.V18738= on NM_003319.4) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs767194702, COSV59899497; called by muse, mutect2, varscan2
- TTN | c.25110G>A p.K8370= (on ENST00000591111; = p.K7443= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/374 reads (29%) | catalogued as COSV59899522; called by muse, mutect2, varscan2
- UBA1 | c.1428G>C p.A476= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs145317174, COSV60111310; called by muse, mutect2, varscan2
- UGDH | c.964C>T p.L322= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as COSV57096752; called by muse, varscan2
- UNC13D | c.351G>A p.V117= | Silent (SNP) | VAF 111/329 reads (34%) | catalogued as COSV52883094, COSV52885175; called by muse, mutect2, varscan2
- VPS13B | c.5235C>G p.L1745= | Silent (SNP) | VAF 16/282 reads (6%) | catalogued as COSV62133840; called by muse, mutect2
- WDR75 | c.1278G>A p.K426= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV59104772; called by muse, mutect2, varscan2
- YOD1 | c.570A>T p.V190= | Silent (SNP) | VAF 120/226 reads (53%) | catalogued as COSV60005905; called by muse, mutect2, varscan2
- ZBTB18 | c.522G>A p.R174= | Silent (SNP) | VAF 61/114 reads (54%) | catalogued as COSV62396303; called by muse, mutect2, varscan2
- ZDHHC1 | c.600C>G p.V200= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV62214600; called by muse, mutect2, varscan2
- ZFHX3 | c.11004C>T p.L3668= | Silent (SNP) | VAF 141/400 reads (35%) | catalogued as COSV51709315; called by muse, mutect2, varscan2
- ZNF8 | c.1293G>A p.L431= | Silent (SNP) | VAF 82/214 reads (38%) | catalogued as COSV52186590; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156873 G>A | 3'Flank (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700933 G>C | 3'Flank (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- CKAP5 | c.4027+211C>T | Intron (SNP) | VAF 134/406 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.6751C>G | RNA (SNP) | VAF 70/161 reads (43%) | catalogued as COSV61768305; called by muse, mutect2, varscan2
- FANCD2 | chr3:10101262 G>C | 3'Flank (SNP) | VAF 36/55 reads (65%) | catalogued as COSV55033131; called by muse, mutect2, varscan2
- NUP214 | c.6075-832G>A | Intron (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34577605 G>A | 5'Flank (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280412 G>C | 5'Flank (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
